Surgical pathology report (de-identified scan), TCGA case TCGA-23-1027, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1027-01A (Primary Tumor).

[page 1 of 3]
Path #:
Pathologist:
Assistant:
Date of Procedure:
Date Received:

SURGICAL PATHOLOGY REPORT

SPECIMEN(S) SUBMITTED: A. PERITONEAL BIOPSY, B. VAGINAL BIOPSY, C. CUL DE SAC BIOPSY, D. RIGHT PELVIS, E. LEFT PELVIS, F. SMALL BOWEL ADHESION, G. TRANSVERSE COLON ADHESION, H. ANTERIOR ABDOMINAL WALL ADHESION, I. LESSER OMENTUM, J. RETROPERITONEUM, K. ANTERIOR ABDOMINAL WALL

DIAGNOSIS:

A. PERITONEAL BIOPSY:

- Benign mesothelial inclusion cyst with reactive stroma

B. VAGINAL BIOPSY:

- Benign squamous epithelium and vascularized fibroconnective tissue with acute inflammation and reactive changes

C. CUL DE SAC BIOPSY:

- Fibroconnective tissue with pigmented histiocytes, foreign body type giant cell reaction and extensive calcifications
- No definite carcinoma seen

D. RIGHT PELVIS, BIOPSY:

- Tiny clusters of highly atypical cells consistent with metastatic carcinoma (see Note)

E. LEFT PELVIS, BIOPSY:

- Tiny cluster of highly atypical cells consistent with metastatic carcinoma

F. SMALL BOWEL ADHESION, BIOPSY:

- Fibroconnective tissue with acute and chronic inflammation
- No definite carcinoma seen

G. TRANSVERSE COLON ADHESION, BIOPSY:

- Benign fibroadipose tissue with focal reactive mesothelial hyperplasia
- No definite carcinoma seen

H. ANTERIOR ABDOMINAL WALL ADHESION, BIOPSY:

- Benign vascularized fibroconnective tissue
- No definite carcinoma seen

I. LESSER OMENTUM, BIOPSY:

- Mature adipose tissue and two benign lymph nodes
- No carcinoma seen

J. RETROPERITONEUM, BIOPSY:

- Dense fibrous tissue with calcifications
- No definite carcinoma seen

K. ANTERIOR ABDOMINAL WALL, BIOPSY:

Patient Case(s)

[page 2 of 3]
PATH #:

NOTE: Atypical cells are negative for calretinin and CK5/6.

HISTORY: Bowel evisceration through vagina

MICROSCOPIC:
See diagnosis.

GROSS:

A. PERITONEAL BIOPSY

Labeled with the patient's name, labeled "peritoneal biopsy", and received in formalin is a thin-walled clear fluid-filled cyst measuring 1.2 x 0.9 x 0.3 cm. The cyst wall is translucent measuring less than 0.1 cm in thickness. Entirely submitted.

A1. 2

B. VAGINAL BIOPSY

Labeled with the patient's name, labeled "vaginal biopsy", and received in formalin is a soft tan tissue fragment measuring 1.0 x 0.5 x 0.5 cm. Entirely submitted.

B1. Multiple

C. CUL DE SAC BIOPSY

Labeled with the patient's name, labeled "cul de sac biopsy", and received in formalin are two soft tan tissue fragments measuring 1.3 x 0.5 x 0.5 cm together. Entirely submitted.

C1. 2

D. RIGHT PELVIS

Labeled with the patient's name, labeled "right pelvis", and received in formalin is a soft tan tissue fragment measuring 0.5 x 0.3 x 0.2 cm. Entirely submitted.

D1. 1

E. LEFT PELVIS

Labeled with the patient's name, labeled "left pelvis", and received in formalin is a soft tan tissue fragment measuring 0.6 x 0.4 x 0.3 cm. Entirely submitted.

E1. 1

F. SMALL BOWEL ADHESION

Labeled with the patient's name, labeled "small bowel adhesion", and received in formalin is a soft tan tissue fragment measuring 2.0 x 1.0 x 0.3 cm. Entirely submitted.

F1. 1

G. TRANSVERSE COLON ADHESION

Labeled with the patient's name, labeled "transverse colon adhesion", and received in formalin is a 0.8 x 0.5 x 0.3 cm soft tan tissue fragment. Entirely submitted.

G1. 1

H. ANTERIOR ABDOMINAL WALL ADHESION

Labeled with the patient's name, labeled "anterior abdominal wall adhesion", and received in formalin is a 1.3 x 0.5 x 0.3 cm soft tan tissue fragment and clotted blood. Entirely submitted.

H1. 1

I. LESSER OMENTUM

[page 3 of 3]
PATH #:

Labeled with the patient's name, labeled "lesser omentum", and received in formalin is a portion of omentum measuring 2.5 x 1.5 x 1.0 cm. Entirely submitted.

II. 2

J. RETROPERITONEUM

Labeled with the patient's name, labeled "retroperitoneum", and received in formalin is a soft tan tissue fragment measuring 2.0 x 1.0 x 0.2 cm. Entirely submitted.

J1. 3

K. ANTERIOR ABDOMINAL WALL

Labeled with the patient's name, labeled "anterior abdominal wall", and received in formalin is a soft tan tissue fragment measuring 0.5 x 0.4 x 0.3 cm. Entirely submitted.

K1. 1

Gross dictated by

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

Source: NCI Genomic Data Commons file 40edbaee-6ba9-4e41-96a2-3d2d18e40ac9 (TCGA-23-1027.568C3873-A64C-4D46-8001-EF3EC63750ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).